Somatic mutation profile of tumor specimen MMRF_2746_1_BM_CD138pos (aliquot MMRF_2746_1_BM_CD138pos_T1_KHS5U_L14902) from MMRF case MMRF_2746, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2746_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63ba7316-2dd6-41e2-99a0-aacdc2e35991.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2746_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2746_1_PB_WBC_C3_KHS5U_L14903; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8745c9d4-2344-4ab8-9ba7-0be3451846dd

The open-access MAF lists 109 somatic variants for this specimen: 43 protein-altering or splice-affecting, 8 silent, 58 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 33, Intron 13, Silent 8, 3'Flank 7, Frame Shift Del 4, 5'UTR 3, Nonsense Mutation 2, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF4 | c.2077del p.R693Vfs*14 | Frame Shift Del (DEL) | VAF 154/368 reads (42%) | catalogued as COSV51949975; called by mutect2, varscan2
- ARMC2 | c.2557C>T p.Q853* | Nonsense Mutation (SNP) | VAF 155/342 reads (45%) | catalogued as rs746375573; called by muse, mutect2, varscan2
- CAPRIN2 | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 110/317 reads (35%) | catalogued as COSV51834150; called by muse, mutect2, varscan2
- CLEC12A | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as rs533589131, COSV100429535; called by muse, mutect2, varscan2
- COL6A3 | c.5770G>A p.V1924I | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778162038, COSV55088979; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTNNB1 | c.1524+1G>A p.X508_splice | Splice Site (SNP) | VAF 81/205 reads (40%) | catalogued as COSV62693341; called by muse, mutect2, varscan2
- CUL4B | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV100340092; called by muse, mutect2, varscan2
- CUX2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs775532302; called by muse, mutect2, varscan2
- CYP11B2 | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1225768189, COSV59996533; called by muse, mutect2, varscan2
- EREG | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); catalogued as COSV55261596; called by muse, mutect2, varscan2
- FBN2 | c.8470G>A p.A2824T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs868262960, COSV52554077; called by muse, mutect2, varscan2
- HTR1E | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541213, COSV59508784; called by muse, mutect2, varscan2
- IGLV3-10 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs748756674; called by muse, mutect2, varscan2
- NRP2 | c.2444A>C p.D815A (on ENST00000360409 / NM_201266.2; = p.D810A on NM_003872.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV63370562; called by muse, mutect2, varscan2
- OR9A4 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101516479; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1652C>T p.S551F (on ENST00000259318 / NM_001136562.3; = p.S782F on NM_007203.5) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1160652609; called by muse, mutect2
- PKD1 | c.6614C>A p.A2205D | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.173); catalogued as rs544177767; called by muse, varscan2
- SLC2A13 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55121511; called by muse, varscan2
- TMEM131L | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs779648191; called by muse, mutect2, varscan2
- TMEM164 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV55810349; called by muse, mutect2
- TRPM6 | c.5957C>T p.S1986F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62502913, COSV62508020, COSV62525574; called by muse, mutect2, varscan2
- YBX3 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs373340462; called by muse, mutect2, varscan2
- ANXA10 | c.646A>T p.N216Y | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- ASH2L | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- BOP1 | c.2186C>T p.T729I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- CASK | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- CD6 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX57 | c.1885A>G p.I629V | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- EPB41L3 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERAP1 | c.1210T>A p.C404S | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2
- EXOC6B | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FAM120B | c.191G>C p.W64S | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPAT4 | c.538A>T p.I180L | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2BC14 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- IGHV2-70 | c.251_272del p.L84Pfs*13 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by muse*, pindel
- MMUT | c.2032C>T p.H678Y | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.12773C>A p.S4258Y (on ENST00000262304 / NM_001009944.3; = p.S4257Y on NM_000296.4) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- SLC5A9 | c.976A>T p.I326F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- TBC1D12 | c.1127A>C p.K376T | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TRAF3 | c.36_37del p.L13Afs*3 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by pindel, varscan2
- VEZF1 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZW10 | c.19del p.E7Kfs*21 | Frame Shift Del (DEL) | VAF 72/226 reads (32%) | called by mutect2, pindel, varscan2
- ARID5B | c.2151C>T p.I717= | Silent (SNP) | VAF 44/167 reads (26%) | called by muse, mutect2, varscan2
- BLK | c.286C>T p.L96= | Silent (SNP) | VAF 64/188 reads (34%) | called by muse, mutect2, varscan2
- EIF4A2 | c.1146G>A p.K382= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- LIMCH1 | c.2883C>T p.L961= | Silent (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- NEK5 | c.945G>A p.R315= | Silent (SNP) | VAF 61/72 reads (85%) | catalogued as COSV100839232; called by muse, mutect2, varscan2
- SIM2 | c.892C>T p.L298= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV51768570; called by muse, mutect2, varscan2
- SLC5A9 | c.975G>A p.K325= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- VWCE | c.687G>A p.E229= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs146063893; called by muse, mutect2, varscan2
- AC134312.1 | n.563G>A | RNA (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- AC144573.1 | c.*470T>C | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- AL359195.2 | n.92G>A | RNA (SNP) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- ALDH1L1 | c.128-855A>G | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- ARHGAP24 | c.391+7159C>T | Intron (SNP) | VAF 89/179 reads (50%) | catalogued as rs201425808, COSV51988451; called by muse, mutect2, varscan2
- ARHGAP9 | c.*241G>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- ARMC2 | c.*434C>A | 3'UTR (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- ATG7 | c.2079+19955C>T | Intron (SNP) | VAF 12/63 reads (19%) | catalogued as COSV61611512; called by muse, mutect2, varscan2
- B4GALT4 | c.903-745C>T | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- C10orf53 | c.*871A>T | 3'UTR (SNP) | VAF 56/124 reads (45%) | called by muse, mutect2, varscan2
- C10orf67 | c.*66G>T | 3'UTR (SNP) | VAF 55/364 reads (15%) | called by mutect2, varscan2
- CDC73 | c.*533C>T | 3'UTR (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- CDK8 | c.*1030dup | 3'UTR (INS) | VAF 18/26 reads (69%) | catalogued as rs1306316810; called by mutect2, varscan2
- CYP3A7 | c.-65C>T | 5'UTR (SNP) | VAF 83/273 reads (30%) | called by muse, mutect2, varscan2
- DDX10 | c.*341T>A | 3'UTR (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- EIF3G | c.152-58C>A | Intron (SNP) | VAF 97/171 reads (57%) | called by muse, mutect2, varscan2
- ELK4 | c.*5482T>C | 3'UTR (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- FGF16 | c.*233T>C | 3'UTR (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- FGFR2 | c.*1220C>G | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2, varscan2
- FIGN | c.*397T>C | 3'UTR (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- GAPVD1 | chr9:125366654 G>A | 3'Flank (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- GLIS1 | c.*79C>A | 3'UTR (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- GRAP2 | c.*571G>A | 3'UTR (SNP) | VAF 58/145 reads (40%) | catalogued as rs1424751591; called by muse, mutect2, varscan2
- GULP1 | c.844-245T>A | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- HDAC2 | c.*2799A>C | 3'UTR (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- HOXB3 | chr17:48545614 T>A | 3'Flank (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- IL7R | c.*2046G>A | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- LAMA3 | c.-170C>G | 5'UTR (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- LPP | c.*1279A>T | 3'UTR (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- LRRC2 | chr3:46517868 T>C | 3'Flank (SNP) | VAF 83/162 reads (51%) | called by muse, mutect2, varscan2
- LRRC49 | c.105+987C>T | Intron (SNP) | VAF 97/227 reads (43%) | called by muse, mutect2, varscan2
- LYRM2 | c.*2641C>A | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- MAP1LC3B | c.40+59C>T | Intron (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- MBNL3 | chrX:132374538 C>A | 3'Flank (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- MKRN3 | c.*569A>C | 3'UTR (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- MYOCD | chr17:12767756 C>T | 3'Flank (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- NEXMIF | c.*2512C>A | 3'UTR (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- OSR2 | c.*38C>T | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- PATZ1 | c.1272-74C>T | Intron (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- PCDH11X | c.*3207A>C | 3'UTR (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- PDCD1 | c.*598G>A | 3'UTR (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- PDE1C | c.751-14T>C | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- PPCDC | c.*955T>G | 3'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- PRKG1 | c.*2063G>A | 3'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- PSMA4 | c.46+45G>A | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as rs1160074096; called by muse, mutect2, varscan2
- RAPGEF3 | chr12:47736143 A>C | 3'Flank (SNP) | VAF 61/156 reads (39%) | called by muse, mutect2, varscan2
- SESN2 | c.-106G>A | 5'UTR (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- SGCE | c.*35T>A | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- SLC5A9 | c.691+82G>T | Intron (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2
- SOCS6 | c.*511A>G | 3'UTR (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.*2495dup | 3'UTR (INS) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- STEAP4 | c.*4999_*5015del | 3'UTR (DEL) | VAF 68/180 reads (38%) | called by mutect2, pindel, varscan2
- STS | c.*2711T>A | 3'UTR (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2
- TBRG4 | c.412-259T>G | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- ZNF10 | c.*335T>A | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- ZNF711 | chrX:85272474 C>T | 3'Flank (SNP) | VAF 24/115 reads (21%) | catalogued as rs1394969934; called by muse, mutect2, varscan2
- ZNF891 | c.*264G>T | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- ZRANB3 | c.*2062T>A | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
